FM case AD10521 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/4807d0b6-2bd6-4ba6-96d8-de8951ac1423

Female, 76.9 years: Papillary serous adenocarcinoma (ICD-O-3 8460/3) of the uterus; metastasis biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
